Somatic mutation profile of tumor specimen ALCH-B0AV-TTP1-A (aliquot ALCH-B0AV-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B0AV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.3 years (22,394 days).
Specimen ALCH-B0AV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3471cc48-e2dc-4247-83eb-1eae9cb2190f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AV-NB1-A (Blood Derived Normal), aliquot ALCH-B0AV-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56c9beea-8f1f-48bf-ae7e-18eb1cd5f656

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 3, Intron 2, 3'Flank 2, 5'UTR 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 668/938 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AHRR | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs753370250; called by muse, mutect2
- CAPN10 | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as rs747049929, COSV54379827; called by muse, mutect2, varscan2
- JRKL | c.838T>C p.S280P | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1041346702; called by muse, mutect2
- PPP1R12A | c.3091T>A p.*1031Kext*71 | Nonstop Mutation (SNP) | VAF 26/161 reads (16%) | catalogued as rs75582066, COSV54109652; called by muse, varscan2
- SCN2A | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs867268264; ClinVar: uncertain significance; called by muse, mutect2
- SPATA31A6 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV60533696; called by muse, mutect2, varscan2
- TP53 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs730882003, COSV52761693, COSV52809012, COSV52965683; ClinVar: uncertain significance; called by muse, mutect2
- TRPM6 | c.5557C>A p.P1853T | Missense Mutation (SNP) | VAF 25/536 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100666331; called by muse, mutect2
- ALOXE3 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL3A1 | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 25/383 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.266); called by muse, mutect2
- CSMD3 | c.3218G>A p.G1073E (on ENST00000297405 / NM_001363185.1; = p.G969E on NM_052900.3) | Missense Mutation (SNP) | VAF 23/551 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- DHX40 | c.2108A>G p.N703S | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KDM4A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- KDM5C | c.963+8C>T | Splice Region (SNP) | VAF 10/213 reads (5%) | called by muse, mutect2
- MS4A12 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); called by muse, mutect2
- MYO10 | c.2869A>G p.I957V | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUSAP1 | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- PDE11A | c.2208C>A p.H736Q | Missense Mutation (SNP) | VAF 33/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PLEKHA6 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TRPC5 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRPM7 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.091); called by muse, varscan2
- CFAP69 | c.1020C>T p.A340= | Silent (SNP) | VAF 12/201 reads (6%) | catalogued as rs1267988209; called by muse, mutect2
- EGFR | c.2574G>T p.L858= | Silent (SNP) | VAF 664/932 reads (71%) | catalogued as rs397517129, COSV51848696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA8 | c.756C>T p.C252= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs763589461; called by muse, mutect2, varscan2
- AC244258.1 | n.311-5019C>G | Intron (SNP) | VAF 9/178 reads (5%) | catalogued as rs1258170318; called by muse, mutect2
- ADAR | c.-982T>G | 5'UTR (SNP) | VAF 10/46 reads (22%) | catalogued as rs965815348; called by muse, mutect2, varscan2
- HOXC10 | chr12:53991801 G>A | 3'Flank (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- MDGA2 | c.1525+1905C>A | Intron (SNP) | VAF 11/190 reads (6%) | called by muse, mutect2
- PRCD | chr17:76544190 A>C | 3'Flank (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
